Gene-level copy-number profile of tumor specimen TCGA-2G-AAHJ-05A from TCGA case TCGA-2G-AAHJ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 51.1 years (18,658 days).
Specimen TCGA-2G-AAHJ-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9ce87cfc-441e-43d8-8188-bb455cc1eb48.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/f27f5bef-7be0-4c76-8a1f-5c7721fa1bc8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,856; copy number 2: 35,825; copy number 3: 20,232.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
